Surgical pathology report (de-identified scan), TCGA case TCGA-ZS-A9CD, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Tayside Tissue Bank, specimen TCGA-ZS-A9CD-01A (Primary Tumor).

[page 1 of 2]
ICP-0-3
Carcinoma, hepatocellular NOS 8170/3
Site Liver C22.0
JAS 5/19/14

Nature of Specimen(s)

Right lobe of liver

Clinical Information Supplied

Right hepatectomy. Past medical history of NIDDM.

MALE

Macro Report

PROCUREMENT DATE:

Received was an 851g right hepatectomy specimen measuring 201 x 103 x up to 111mm. The resection margin measured 179 x 101mm. Beneath the diaphragmatic surface there was evidence of pale tumour in the subcapsular area which on sectioning showed a pale lobulated tumour mass measuring 43mm in maximum. Further sectioning revealed further smaller areas of tumour ranging in size from 4mm up to 17mm. These all appear to be within the general area of the main tumour mass. The background liver parenchyma appeared rather fatty. Towards the inferior portion of the liver a further solitary tumour mass 15mm in maximum was present, this being some 17mm from the resection margin.

Blocks: A - smaller inferior lesion to closest margin, B - whole section of small lesion, C&D - whole section from larger tumour mass to closest resection margin, E-K - sections from tumour mass, L-N - background liver.

Micro Report

Histology shows multifocal hepatocellular carcinoma with a variety of architectural patterns including nodules with marked steatosis and Mallory's hyaline and other areas in which there is a rather more nested and trabecular pattern of growth. The tumour is completely excised by a margin of at least 14mm from the surgical margin. There is no evidence of capsular breach or peritoneal surface involvement.

Page 1 of 2

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

[page 2 of 2]
The background liver shows established bridging fibrosis, focally amounting to early cirrhosis (confirmed on Van Gieson and reticulin stains). There is moderate, predominantly macrovesicular, steatosis. Areas of periportal, interface and focal lobular inflammation are noted, however, these may be related to the presence of tumour. The inflammatory infiltrate is composed predominantly of small lymphocytes. Occasional plasma cells and eosinophils are also noted.

An orcein stain for copper associated protein is negative.

A Perls' stain for iron is negative.

No PAS positive diastase resistant globules are identified.

Summary

Overall the features are those of multifocal hepatocellular carcinoma arising in a background of cirrhotic liver. The tumour is completely excised by a margin of at least 14mm.

Signature of Pathologist(s)

Page 2 of 2

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

Source: NCI Genomic Data Commons file c373ea90-7b2c-4308-b298-961a4375a3af (TCGA-ZS-A9CD.11C6E09D-89C3-43B9-B884-247278242067.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).